PECGS case C083-000053 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/daccf897-dc61-4892-8fe5-9c80a10f2f03

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 56 years; Year of birth: 1966; Vital status: Dead; Cause of death: Cancer Related; Education level: High School Graduate or GED.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 56.3 years (20,564 days); AJCC clinical stage: Stage IIIC; Progression or recurrence: yes; Days to last follow up: 371 days (1.0 years).

Other clinical attributes
- Menopause status: Postmenopausal.

Biospecimens (2 samples)
- Sample C083-000053_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000053_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
